Somatic mutation profile of tumor specimen 0DAEHO from CCDI case PBBJHD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.9 years (2,534 days).
Specimen 0DAEHO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73ec27a7-927e-488d-8de3-3ea78886067b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAEHS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9af55e1f-afd2-4d27-b74a-951d3a2d1cd3

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Silent 2, In Frame Del 1, Splice Site 1, 5'UTR 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 207/1096 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC008397.2 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs775763570; called by muse, mutect2, varscan2
- FOXI3 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1001058870; called by muse, mutect2, varscan2
- MATR3 | c.1779-1G>A p.X593_splice | Splice Site (SNP) | VAF 18/718 reads (3%) | catalogued as COSV100735343, COSV63080772; called by muse, mutect2
- PCNX1 | c.5506C>T p.R1836* | Nonsense Mutation (SNP) | VAF 161/754 reads (21%) | catalogued as rs975081302, COSV53091725; called by muse, mutect2, varscan2
- PGBD5 | c.882C>A p.C294* (on ENST00000525115; = p.C363* on NM_001258311.2) | Nonsense Mutation (SNP) | VAF 117/637 reads (18%) | catalogued as COSV58410960; called by muse, mutect2, varscan2
- TECTA | c.5909C>G p.A1970G | Missense Mutation (SNP) | VAF 20/842 reads (2%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV99878808; called by muse, mutect2
- ZBED5 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as rs780011941; called by muse, mutect2
- ANKRD27 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 83/404 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.258); called by mutect2, varscan2
- ARID2 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2, varscan2
- CTNNB1 | c.91_96del p.L31_D32del | In Frame Del (DEL) | VAF 170/582 reads (29%) | called by mutect2, varscan2
- DNAH6 | c.4864G>A p.A1622T | Missense Mutation (SNP) | VAF 179/908 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYH13 | c.3298G>T p.D1100Y | Missense Mutation (SNP) | VAF 118/906 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NCAM2 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 465/1172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PCDH8 | c.2225C>T p.S742L | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- TRIM51GP | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 24/764 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.423); called by muse, mutect2
- ATP6V1E1 | c.378G>A p.Q126= | Silent (SNP) | VAF 96/512 reads (19%) | called by muse, mutect2, varscan2
- TIGD5 | c.1260C>T p.G420= | Silent (SNP) | VAF 57/268 reads (21%) | called by muse, mutect2, varscan2
- DIO2 | c.*1546del | 3'UTR (DEL) | VAF 20/116 reads (17%) | catalogued as rs397711593; called by mutect2, varscan2
- MTPN | c.-71G>A | 5'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- PHC1 | c.225+27G>A | Intron (SNP) | VAF 17/196 reads (9%) | catalogued as rs200804190; called by muse, mutect2, varscan2
